Gene-level copy-number profile of specimen HCM-SANG-0280-C18-85A from HCMI case HCM-SANG-0280-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G3.
Specimen HCM-SANG-0280-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3593b277-2aec-40b8-a8f4-3baa661624c2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0280-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/824ec65f-807f-44f2-a61a-33eef8d6da59

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,967; copy number 2: 48,074; copy number 3: 5,293; copy number 4: 1,575.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,966. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
